TCGA case TCGA-A2-A04P — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Walter Reed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ccd4a24b-d8cc-4686-9dee-c98b0c5a8d21

Demographics
Sex at birth: female; Race: black or african american; Age at index: 36 years; Vital status: Dead; Days to death: 548 days (1.5 years).

Diagnoses (7)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 36.2 years (13,238 days); Year of diagnosis: 2003; Method of diagnosis: Excisional Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N3c; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 18; Lymph nodes tested: 20; Micrometastasis present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 69 days; Days to treatment end: 180 days; Number of cycles: 12; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Initial disease status: Recurrent Disease; Days to treatment start: 180 days; Days to treatment end: 242 days; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 193 days; Days to treatment end: 237 days; Treatment dose: 4,393 cGy; Number of fractions: 23; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 193 days; Days to treatment end: 237 days; Treatment dose: 10,620 cGy; Number of fractions: 59; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel + Gemcitabine Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 242 days; Days to treatment end: 303 days; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 303 days; Days to treatment end: 424 days (1.2 years); Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Vinorelbine Tartrate; Initial disease status: Progressive Disease; Days to treatment start: 424 days (1.2 years); Days to treatment end: 424 days (1.2 years); Number of cycles: 1; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Exemestane; Initial disease status: Progressive Disease; Days to treatment start: 424 days (1.2 years); Prescribed dose: 25; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment end: 237 days; Treatment dose: 900 cGy; Number of fractions: 3; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: Re-Excision; Initial disease status: Initial Diagnosis; Margin status: Involved; Treatment anatomic sites: Breast.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Involved; Treatment anatomic sites: Breast.
2. Metastasis of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Bone, NOS. Age at diagnosis: 36.5 years (13,340 days); Days to diagnosis: 102 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.
3. Recurrence of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Thorax, NOS. Age at diagnosis: 36.7 years (13,417 days); Days to diagnosis: 179 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 179 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
4. Diagnosis record without a diagnosis name: Age at diagnosis: 36.7 years (13,417 days); Days to diagnosis: 179 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 179 days; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Distant Site, for progressive disease.
5. Diagnosis record without a diagnosis name: Age at diagnosis: 36.7 years (13,418 days); Days to diagnosis: 180 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS to Locoregional Site, for recurrent disease; Surgery, NOS to Distant Site, for progressive disease.
6. Metastasis of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Lung, NOS. Age at diagnosis: 36.7 years (13,418 days); Days to diagnosis: 180 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
7. Metastasis of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Liver. Age at diagnosis: 37.1 years (13,551 days); Days to diagnosis: 313 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (5 entries)
- Day 102 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 102 days.
- Day 179 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Thorax, NOS; Days to recurrence: 179 days.
- Day 180 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 180 days.
- Day 313 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 313 days.
- Days to follow up: 548 days (1.5 years); Disease response: With Tumor.

Molecular and laboratory tests
- ERBB2 (FISH): 1.3; Specialized molecular test: Signal ratio.
- ERBB2 (FISH): 1; Specialized molecular test: Signal ratio.
- ERBB2 amplification (FISH): Negative.
- ESR1 (IHC): Negative.
- ESR1 (IHC): Negative; Test value range: <10%.
- PGR (IHC): Negative.
- PGR (IHC): Negative; Test value range: <10%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A2-A04P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 250 mg.
  Slide TCGA-A2-A04P-01A-03-BSC: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 9; Percent lymphocyte infiltration: 12; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-A2-A04P-01A-03-TSC: Section location: Top; Percent tumor cells: 84; Percent tumor nuclei: 85; Percent normal cells: 7; Percent necrosis: 2; Percent stromal cells: 7; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-A2-A04P-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A2-A04P-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: With tumor; Her2 cent17 ratio: 1.3; Axillary staging method: Axillary lymph node dissection alone; Surgical procedure first: Lumpectomy; Surgery for positive margins: Mastectomy NOS; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Micromet detection by IHC: No; Margin status reexcision: Positive; Margin status: Positive; Lymph nodes examined IHC count: 0; Prospective collection: No; Retrospective collection: Yes; Er status IHC Percent Positive: <10%; Pr status IHC percent positive: <10%.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left.
- Follow-up form 1: Tumor status: With tumor; New tumor event surgery: Yes; Her2 cent17 ratio: 1.0; New tumor event surgery met: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 2: Tumor status: With tumor; New tumor event surgery: No; New tumor event surgery met: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form 3: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment 1: Regimen number: 8; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 3; Pharmaceutical therapy drug name: Taxotere; Therapy regimen: Progression.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 3: Regimen number: 5; Pharmaceutical therapy drug name: Adriamycin; Therapy regimen: Progression.
- Drug treatment 4: Regimen number: 7; Pharmaceutical therapy drug name: Navelbine; Therapy regimen: Progression.
- Drug treatment 5: Regimen number: 6; Therapy regimen: Progression.
- Drug treatment 6: Regimen number: 1; Pharmaceutical therapy drug name: Taxol.
- Drug treatment 7: Regimen number: 2; Pharmaceutical therapy drug name: Xeloda.
- Drug treatment 8: Regimen number: 4; Pharmaceutical therapy drug name: Gemzar; Therapy regimen: Progression.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 548 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 548 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 102 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A2-A04P-01A-31D-A036-01): tumor purity 0.6, ploidy 3.26, whole-genome doublings 1.
